Somatic mutation profile of tumor specimen C3N-02142-03 (aliquot CPT0118510006) from CPTAC case C3N-02142, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.4 years (23,162 days).
Specimen C3N-02142-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f490f8e-f757-4f33-ba80-f5fb511362b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02142-31 (Blood Derived Normal), aliquot CPT0119750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/331a5878-7939-48ea-b58e-a5c71465aa30

The open-access MAF lists 851 somatic variants for this specimen: 571 protein-altering or splice-affecting, 173 silent, 107 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 489, Silent 173, Intron 49, Nonsense Mutation 40, Splice Site 20, RNA 18, 3'UTR 14, 5'UTR 11, Splice Region 9, Frame Shift Del 9, 5'Flank 8, 3'Flank 7.

Variants (750 of 851; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 174/502 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.1879G>T p.A627S (on ENST00000614293; = p.A597S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.95); catalogued as COSV99688505; called by muse, mutect2
- ABCC2 | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 51/312 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99059785; called by muse, mutect2, varscan2
- ABL2 | c.3430G>T p.E1144* (on ENST00000502732 / NM_007314.4; = p.E1129* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 64/370 reads (17%) | catalogued as COSV61012123; called by muse, mutect2, varscan2
- ADAMTS15 | c.2564G>C p.C855S | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100143067; called by muse, mutect2, varscan2
- ADCY8 | c.2521G>T p.V841L | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs1554605126; called by muse, mutect2, varscan2
- ADGRF2 | c.2111A>T p.H704L | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1364310732; called by muse, mutect2
- AGK | c.593A>G p.E198G | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.211); catalogued as rs781292634; called by muse, mutect2
- ALOX15 | c.989T>C p.L330P | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53398593; called by muse, mutect2, varscan2
- AMY2A | c.151G>T p.G51* | Nonsense Mutation (SNP) | VAF 70/444 reads (16%) | catalogued as rs761137032, COSV70214313, COSV70214392; called by muse, mutect2, varscan2
- ANGPT1 | c.1038G>T p.M346I | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV52457633; called by muse, varscan2
- ANK2 | c.9048G>T p.E3016D | Missense Mutation (SNP) | VAF 57/322 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100001736; called by muse, mutect2, varscan2
- ANXA6 | c.609G>T p.L203F | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62905770; called by muse, mutect2, varscan2
- ASB5 | c.203G>T p.W68L | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as COSV56672151; called by muse, mutect2, varscan2
- ATP8A2 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54935014, COSV54970485; called by muse, mutect2
- BBOX1 | c.498del p.R168Gfs*32 | Frame Shift Del (DEL) | VAF 23/219 reads (11%) | catalogued as COSV54191977, COSV99589911; called by mutect2, pindel
- BRINP3 | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 77/377 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as rs376755713; called by muse, mutect2, varscan2
- C2orf49 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs199899473; called by muse, mutect2
- C4orf45 | c.220G>T p.V74F | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV71700751; called by muse, mutect2, varscan2
- CACNA1I | c.854C>A p.P285Q | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV60811430; called by muse, mutect2
- CARMIL2 | c.1747-1G>C p.X583_splice | Splice Site (SNP) | VAF 60/311 reads (19%) | catalogued as COSV100576450; called by muse, mutect2, varscan2
- CCDC178 | c.80A>T p.K27M | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1222436914; called by muse, mutect2, varscan2
- CDH23 | c.4204G>T p.V1402L | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs747086873; called by muse, mutect2
- CEP164 | c.2106G>T p.E702D | Missense Mutation (SNP) | VAF 77/382 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1291164061; called by muse, mutect2, varscan2
- CEP170 | c.3911G>T p.R1304M | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100316240; called by muse, mutect2, varscan2
- CEP63 | c.398G>T p.R133M | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as COSV59675856; called by muse, mutect2, varscan2
- CFAP91 | c.1100A>T p.Y367F | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as rs771950038, COSV56344462; called by muse, mutect2, varscan2
- CNOT6 | c.1081del p.H361Tfs*11 | Frame Shift Del (DEL) | VAF 28/255 reads (11%) | catalogued as COSV56161955; called by mutect2, pindel, varscan2
- COL22A1 | c.2639G>T p.G880V | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57336330; called by muse, mutect2, varscan2
- COL25A1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV67660834; called by muse, mutect2, varscan2
- COL4A4 | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV61634819; called by muse, mutect2
- COL4A6 | c.1429+1G>T p.X477_splice | Splice Site (SNP) | VAF 23/95 reads (24%) | catalogued as COSV57865296; called by muse, mutect2, varscan2
- CPS1 | c.566C>A p.P189H | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV51820608; called by muse, mutect2
- CSMD1 | c.8227G>C p.G2743R (on ENST00000520002; = p.G2742R on NM_033225.6) | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59359578, COSV59372481; called by muse, mutect2
- CSMD3 | c.10534C>A p.Q3512K (on ENST00000297405 / NM_001363185.1; = p.Q3343K on NM_052900.3) | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs775301573; called by muse, mutect2
- CTNNA2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as rs1245962200, COSV63557850; called by muse, mutect2, varscan2
- CYLC1 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV61414271; called by muse, mutect2, varscan2
- CYLC1 | c.296C>A p.P99Q | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV61413987; called by muse, mutect2, varscan2
- CYLC2 | c.179C>A p.S60Y | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as COSV100872446; called by muse, mutect2
- DGAT2 | c.377G>A p.W126* | Nonsense Mutation (SNP) | VAF 16/250 reads (6%) | catalogued as COSV57177581; called by muse, mutect2
- DLGAP2 | c.788C>A p.A263E | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.482); catalogued as rs375416274, COSV101422983, COSV70099599, COSV99073642; called by muse, mutect2, varscan2
- DNAH3 | c.4217C>A p.P1406H | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338539793; called by muse, mutect2
- DNAI1 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 37/532 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.097); catalogued as rs867966352, COSV99646921; called by muse, mutect2
- DNMBP | c.3347G>T p.G1116V | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100144006; called by muse, mutect2, varscan2
- DRC1 | c.386C>A p.T129N | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as COSV56534197; called by muse, mutect2, varscan2
- EAPP | c.289G>C p.A97P | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.35); catalogued as COSV51653611; called by muse, mutect2
- EIF4ENIF1 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 28/411 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764631776, COSV100349445; called by muse, mutect2
- ERGIC3 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 27/343 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs1305916485, COSV54136036; called by muse, mutect2
- ESRRG | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 75/341 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV63161445; called by muse, mutect2, varscan2
- F13B | c.559G>C p.A187P | Missense Mutation (SNP) | VAF 107/471 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as COSV100803229; called by muse, mutect2, varscan2
- F2R | c.493G>C p.G165R | Missense Mutation (SNP) | VAF 48/513 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375693604, COSV100058491; called by muse, mutect2
- FAF2 | c.345-1G>T p.X115_splice | Splice Site (SNP) | VAF 25/379 reads (7%) | catalogued as COSV56133303; called by muse, mutect2
- FKBP15 | c.1394G>T p.G465V | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as rs1457600285; called by muse, mutect2, varscan2
- FKBP15 | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs868855426; called by muse, mutect2, varscan2
- FLG | c.10968C>A p.H3656Q | Missense Mutation (SNP) | VAF 52/826 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.908); catalogued as rs774161190; called by muse, mutect2
- FLNC | c.6161G>T p.G2054V | Missense Mutation (SNP) | VAF 34/442 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57955776; called by muse, mutect2
- FN1 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 18/164 reads (11%) | catalogued as COSV60552298; called by muse, mutect2, varscan2
- FOXC2 | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 61/778 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57444193; called by muse, mutect2
- FOXO1 | c.1523G>A p.G508D | Missense Mutation (SNP) | VAF 40/399 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV65427842; called by muse, mutect2, varscan2
- FSCB | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61217395; called by muse, mutect2
- FSHR | c.1591G>C p.V531L | Missense Mutation (SNP) | VAF 15/241 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV58618651; called by muse, mutect2
- GABRA2 | c.1276C>A p.P426T | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734121; called by muse, mutect2, varscan2
- GCM2 | c.582+1G>T p.X194_splice | Splice Site (SNP) | VAF 36/428 reads (8%) | catalogued as rs1252696610; called by muse, mutect2
- GPR61 | c.209C>A p.T70K | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV68177849; called by muse, mutect2
- GUCY1A1 | c.815A>T p.Q272L | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs767881072; called by muse, mutect2, varscan2
- HCN1 | c.2464G>T p.V822F | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.068); catalogued as COSV57498710; called by muse, mutect2
- HCN1 | c.980C>A p.P327Q | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs1000142153, COSV100299882; called by muse, mutect2
- HCN4 | c.2082G>C p.E694D | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV99984384; called by muse, mutect2, varscan2
- HGF | c.1270C>A p.R424S | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.336); catalogued as COSV55945098; called by muse, mutect2, varscan2
- HMCN2 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as rs1428007381; called by muse, mutect2
- IFRD2 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201634662; called by muse, mutect2
- IGKV2D-30 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs761783608; called by mutect2, varscan2
- IL11RA | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 25/337 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs1477700022; called by muse, mutect2
- IL20RA | c.1486A>G p.S496G | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs773632626; called by muse, mutect2, varscan2
- INHBA | c.820G>C p.G274R | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.572); catalogued as COSV54219282, COSV54225682; called by muse, varscan2
- JPH2 | c.1084G>T p.V362F | Missense Mutation (SNP) | VAF 16/530 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs1479268157; called by muse, mutect2
- KCNC1 | c.822C>G p.I274M | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs1330514361; called by muse, mutect2
- KCNT2 | c.460-1G>C p.X154_splice | Splice Site (SNP) | VAF 14/132 reads (11%) | catalogued as COSV99652934; called by muse, varscan2
- KDM4E | c.1391T>A p.L464Q | Missense Mutation (SNP) | VAF 32/503 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.159); catalogued as rs781939619; called by muse, mutect2
- KIAA1755 | c.3397G>T p.A1133S | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs1234320271; called by muse, mutect2
- KIF2B | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 15/329 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV52132689; called by muse, mutect2
- KIFBP | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV62556372; called by muse, mutect2
- KIFC1 | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 54/338 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV65737954; called by muse, mutect2, varscan2
- KLHL4 | c.971C>A p.P324Q | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV64146699; called by muse, mutect2, varscan2
- LCNL1 | c.161C>A p.T54N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.903); catalogued as rs766182138; called by muse, mutect2, varscan2
- LPAR5 | c.770A>C p.Y257S | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs776452407; called by muse, mutect2, varscan2
- MAGI2 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62680544; called by muse, varscan2
- MARK2 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 22/353 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100158073; called by muse, mutect2
- MASP1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 35/588 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as rs767493716, COSV99396596; called by muse, mutect2
- MELTF | c.570G>T p.R190S | Missense Mutation (SNP) | VAF 88/345 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as COSV56380656; called by muse, mutect2, varscan2
- MGAM2 | c.2363G>T p.G788V | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV72176202; called by muse, mutect2, varscan2
- MIA3 | c.2509C>A p.Q837K | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV60516606; called by muse, mutect2, varscan2
- MINDY4 | c.1127G>T p.R376L | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV54672919, COSV54676651; called by muse, mutect2
- MMP12 | c.1330C>A p.Q444K | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV58261777; called by muse, mutect2, varscan2
- MUC4 | c.9903G>T p.E3301D | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.224); catalogued as rs765465215; called by muse, varscan2
- MYOC | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50676796; called by muse, mutect2, varscan2
- N4BP1 | c.1391G>C p.R464T | Missense Mutation (SNP) | VAF 19/373 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV52213285; called by muse, mutect2
- NEURL4 | c.2040G>T p.Q680H | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV59758822; called by muse, mutect2, varscan2
- NIN | c.3076A>G p.T1026A | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774606229; called by muse, mutect2
- NLRP1 | c.3184C>A p.P1062T | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV52577712; called by muse, mutect2, varscan2
- NLRP13 | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV61621131; called by muse, mutect2, varscan2
- NOVA1 | c.827C>A p.A276D | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as COSV57473182; called by muse, mutect2, varscan2
- NSUN3 | c.402G>C p.K134N | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs756803167; called by muse, mutect2, varscan2
- OCA2 | c.1672G>T p.A558S | Missense Mutation (SNP) | VAF 68/436 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as CM085607; called by muse, mutect2, varscan2
- OR10J3 | c.342C>A p.F114L | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.485); catalogued as COSV100171697; called by muse, mutect2
- OR2T12 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 54/698 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1402737053, COSV58776219; called by muse, mutect2
- OR2T6 | c.410G>T p.S137I | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs2226010, COSV100861494; called by muse, mutect2
- OR4A16 | c.613T>A p.C205S | Missense Mutation (SNP) | VAF 36/439 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.26); catalogued as rs145729272; called by muse, mutect2
- OR4X2 | c.265T>G p.C89G | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56584814; called by muse, mutect2
- OR51V1 | c.766A>T p.I256F | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs754571332; called by muse, mutect2, varscan2
- OR5H1 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 21/340 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV63402990, COSV99075120; called by muse, mutect2
- OR5L2 | c.479C>A p.S160* | Nonsense Mutation (SNP) | VAF 26/338 reads (8%) | catalogued as rs148523172, COSV65723301, COSV65724665; called by muse, mutect2
- OTOF | c.1291C>A p.R431S | Missense Mutation (SNP) | VAF 64/415 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.506); catalogued as COSV55500181; called by muse, mutect2, varscan2
- PAPSS1 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54493737; called by muse, varscan2
- PCDH7 | c.2808G>T p.K936N | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); catalogued as COSV62338605; called by muse, mutect2
- PCDHB8 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 98/1200 reads (8%) | catalogued as COSV50758042, COSV99176912; called by muse, mutect2
- PCLO | c.10400G>T p.S3467I | Missense Mutation (SNP) | VAF 57/291 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV61669036; called by muse, mutect2, varscan2
- PDHA2 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV54777097, COSV99756520; called by muse, mutect2, varscan2
- PGLS | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1200891607; called by muse, mutect2
- PHF2 | c.650G>T p.W217L | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100823107; called by muse, mutect2
- PKHD1 | c.10464C>A p.N3488K | Missense Mutation (SNP) | VAF 46/331 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.257); catalogued as rs775481784, COSV100945244; called by muse, mutect2, varscan2
- PLEKHG4B | c.1164G>T p.Q388H (on ENST00000283426; = p.Q744H on NM_052909.5) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV99360658, COSV99361289; called by muse, varscan2
- PLXNA1 | c.2809G>T p.V937L | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV52530713; called by muse, mutect2, varscan2
- PLXNA4 | c.4477C>A p.Q1493K | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58121261; called by muse, mutect2, varscan2
- PNMA3 | c.1355C>A p.A452D | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV64722972; called by muse, mutect2, varscan2
- PODXL | c.1300G>A p.E434K (on ENST00000378555 / NM_001018111.3; = p.E402K on NM_005397.4) | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as rs267601287; called by muse, mutect2
- POP1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 32/584 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV62892289; called by muse, mutect2
- PRAMEF1 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 68/459 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV60012693; called by muse, mutect2, varscan2
- PROS1 | c.1795G>T p.D599Y | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101260811, COSV67775334; called by muse, mutect2, varscan2
- PRPF3 | c.-48G>T | Splice Region (SNP) | VAF 36/146 reads (25%) | catalogued as rs1553863264; called by mutect2, varscan2
- PRPF4 | c.1333C>T p.P445S (on ENST00000374198 / NM_001322267.2; = p.P446S on NM_004697.5) | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100950631; called by muse, mutect2
- PTPRN2 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 44/486 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753849491, COSV67030982, COSV67035376; called by muse, mutect2
- RABGAP1L | c.1768G>T p.D590Y | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs865948279; called by muse, mutect2
- RASGRF2 | c.1930G>T p.V644L | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.399); catalogued as COSV54136830; called by muse, mutect2
- RERE | c.4381G>T p.A1461S | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.212); catalogued as COSV61940795; called by muse, mutect2, varscan2
- RHBDF1 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.556); catalogued as COSV99244991; called by muse, mutect2
- RNASE9 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.715); catalogued as COSV100141149, COSV58880061; called by muse, mutect2
- RSPO2 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52643326; called by muse, mutect2, varscan2
- RYR3 | c.3728C>T p.T1243M | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.777); catalogued as rs550824274, COSV101214644; called by muse, mutect2, varscan2
- SHISA9 | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV69638643; called by muse, mutect2, varscan2
- SIX6 | c.607C>G p.R203G | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs886050563; called by muse, mutect2
- SLAIN2 | c.1546A>T p.S516C | Missense Mutation (SNP) | VAF 46/541 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as rs1252836058; called by muse, mutect2
- SLC13A3 | c.1580C>A p.T527K | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324143927, COSV51716411; called by muse, mutect2
- SLC39A12 | c.1533+1G>T p.X511_splice | Splice Site (SNP) | VAF 10/134 reads (7%) | catalogued as COSV66198069; called by muse, mutect2
- SLITRK2 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV59427518; called by muse, mutect2, varscan2
- SNTG1 | c.494C>A p.T165N | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV52452654; called by muse, mutect2, varscan2
- SPHKAP | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 19/242 reads (8%) | catalogued as COSV60874818; called by muse, mutect2
- SRRM3 | c.1399C>A p.P467T | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as rs1554612129; called by muse, mutect2
- STON1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 22/423 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1317534794; called by muse, mutect2
- STS | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV54270807; called by muse, mutect2
- SUPT6H | c.3439G>T p.E1147* | Nonsense Mutation (SNP) | VAF 11/213 reads (5%) | catalogued as COSV58926888; called by muse, mutect2
- TADA2B | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53827552; called by muse, mutect2
- TANC2 | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as CM142622; called by muse, mutect2, varscan2
- TCEANC | c.73G>T p.D25Y (on ENST00000380600 / NM_001297563.2; = p.D55Y on NM_152634.4) | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59039862; called by muse, mutect2, varscan2
- TGM2 | c.440C>A p.A147D | Missense Mutation (SNP) | VAF 38/363 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs138064359; called by muse, mutect2, varscan2
- TMPRSS11E | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs149361074; called by muse, mutect2, varscan2
- TMPRSS5 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs562297984, COSV100244555, COSV55425863; called by muse, mutect2, varscan2
- TNFRSF18 | c.326G>C p.G109A | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60776068; called by muse, mutect2, varscan2
- TNRC6B | c.5379G>T p.W1793C (on ENST00000454349 / NM_001162501.2; = p.W1683C on NM_015088.3) | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57296197; called by muse, mutect2
- TRPS1 | c.3662G>T p.G1221V (on ENST00000220888 / NM_001330599.2; = p.G1234V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/544 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55250944; called by muse, mutect2, varscan2
- UBQLNL | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1182822118; called by muse, mutect2
- UNC80 | c.9584C>T p.P3195L | Missense Mutation (SNP) | VAF 31/407 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1480683722; called by muse, mutect2
- USH2A | c.992G>T p.R331I | Missense Mutation (SNP) | VAF 19/364 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56406578; called by muse, mutect2
- UTP20 | c.7778C>T p.A2593V | Missense Mutation (SNP) | VAF 29/368 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as rs763083231; called by muse, mutect2
- WNT5A | c.977A>G p.N326S | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1368827765; called by muse, mutect2
- ZBP1 | c.1269C>A p.S423R | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV59063907; called by muse, mutect2
- ZIC4 | c.352C>A p.R118S | Missense Mutation (SNP) | VAF 38/366 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV67172353; called by muse, mutect2
- ZNF208 | c.2999C>A p.P1000H | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101236700, COSV68111104; called by muse, mutect2
- ZNF479 | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58635744; called by muse, mutect2
- ZNF479 | c.970C>A p.P324T | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58637230; called by muse, mutect2
- ZNF536 | c.1295C>A p.S432Y | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100834805; called by muse, mutect2, varscan2
- ZSWIM2 | c.643A>T p.S215C | Missense Mutation (SNP) | VAF 52/353 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as COSV54580892; called by muse, mutect2, varscan2
- ABCC11 | c.4117C>A p.L1373I | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ABCC11 | c.1529C>A p.P510H | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.428); called by muse, mutect2
- ABRA | c.722C>A p.P241Q | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACBD6 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 28/592 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); called by muse, mutect2
- ACCSL | c.1707G>T p.*569Yext*? | Nonstop Mutation (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2, varscan2
- ACSBG1 | c.1855C>A p.P619T | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.029); called by muse, mutect2
- ADAM20 | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2
- ADAM23 | c.1191G>C p.K397N | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2
- ADAMTS20 | c.3482G>T p.W1161L | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ADAMTS3 | c.2158A>C p.T720P | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ADD2 | c.2076G>T p.M692I | Missense Mutation (SNP) | VAF 48/377 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRB1 | c.4528G>T p.D1510Y | Missense Mutation (SNP) | VAF 27/293 reads (9%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.65); called by muse, mutect2
- ADGRF5 | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.339); called by muse, mutect2
- AFF1 | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AHNAK | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK2 | c.9901G>T p.V3301L | Missense Mutation (SNP) | VAF 62/672 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.091); called by muse, mutect2
- AK4 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by mutect2, varscan2
- AKR1B1 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 101/587 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKR1C3 | c.710A>T p.E237V | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- ALOXE3 | c.1041del p.A348Pfs*100 | Frame Shift Del (DEL) | VAF 25/113 reads (22%) | called by mutect2, pindel, varscan2
- ANK1 | c.346T>G p.Y116D | Missense Mutation (SNP) | VAF 34/561 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- ANKRD30A | c.916G>A p.A306T (on ENST00000611781; = p.A250T on NM_052997.2) | Missense Mutation (SNP) | VAF 66/556 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, varscan2
- APOB | c.12872A>G p.K4291R | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.327); called by muse, mutect2
- APOBEC4 | c.824C>G p.P275R | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- APPBP2 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 39/169 reads (23%) | called by muse, mutect2, varscan2
- ARHGAP9 | c.189G>T p.L63F | Missense Mutation (SNP) | VAF 88/526 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARV1 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 33/361 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ATP8B4 | c.2588G>T p.R863M | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- B4GALT6 | c.346+1G>T p.X116_splice | Splice Site (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- BACH1 | c.1553G>C p.R518T | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- BCHE | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2
- BCL11A | c.2138G>T p.C713F (on ENST00000335712 / NM_001365609.1; = p.C747F on NM_022893.4) | Missense Mutation (SNP) | VAF 40/385 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BCORL1 | c.3916G>T p.E1306* | Nonsense Mutation (SNP) | VAF 25/104 reads (24%) | called by muse, mutect2, varscan2
- BIRC6 | c.7654G>T p.E2552* | Nonsense Mutation (SNP) | VAF 38/218 reads (17%) | called by muse, mutect2, varscan2
- BPGM | c.699G>T p.Q233H | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.133); called by muse, mutect2
- BUB1B | c.2575A>G p.T859A | Missense Mutation (SNP) | VAF 60/321 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- C20orf173 | c.-218C>A | Splice Region (SNP) | VAF 38/339 reads (11%) | called by muse, varscan2
- C6 | c.2758G>T p.A920S | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.178); called by muse, mutect2
- C9orf131 | c.3158C>A p.A1053D | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.555); called by muse, mutect2
- CAPN14 | c.760C>A p.H254N | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCSER1 | c.2625G>T p.M875I | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CD40LG | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CDC14B | c.1369A>T p.S457C | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); called by muse, mutect2
- CDC14C | c.1212C>A p.C404* (on ENST00000428251; = p.C297* on NM_152627.3) | Nonsense Mutation (SNP) | VAF 17/396 reads (4%) | called by muse, mutect2
- CDHR2 | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 49/486 reads (10%) | called by muse, mutect2, varscan2
- CEP135 | c.1127A>T p.Q376L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP170 | c.4583A>G p.H1528R | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CEP68 | c.2167C>A p.R723S | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- CERT1 | c.1486G>T p.V496F (on ENST00000405807 / NM_001130105.1; = p.V368F on NM_005713.3) | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- CFAP43 | c.3241G>T p.E1081* | Nonsense Mutation (SNP) | VAF 38/196 reads (19%) | called by muse, varscan2
- CFAP46 | c.7411C>A p.L2471M | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CFAP65 | c.5160C>A p.D1720E | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.074); called by muse, mutect2
- CHIT1 | c.121T>G p.F41V | Missense Mutation (SNP) | VAF 56/667 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CIP2A | c.881A>T p.D294V | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- CIP2A | c.531A>T p.Q177H | Missense Mutation (SNP) | VAF 21/255 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLASP2 | c.2786G>C p.G929A | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.091); called by muse, mutect2
- CLCA2 | c.1895T>A p.F632Y | Missense Mutation (SNP) | VAF 45/406 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- CLK1 | c.551del p.G184Efs*5 | Frame Shift Del (DEL) | VAF 18/179 reads (10%) | called by mutect2, pindel, varscan2
- CLTC | c.3157C>T p.P1053S | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.893); called by muse, mutect2
- CMBL | c.395G>A p.C132Y | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- COCH | c.357C>A p.C119* (on ENST00000216361 / NM_001347720.1; = p.C54* on NM_004086.3) | Nonsense Mutation (SNP) | VAF 30/464 reads (6%) | called by muse, mutect2
- COL11A1 | c.4360C>G p.H1454D | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL13A1 | c.1287T>A p.D429E (on ENST00000398978 / NM_001130103.2; = p.D372E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL19A1 | c.1972C>A p.P658T | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL1A2 | c.225+1G>C p.X75_splice | Splice Site (SNP) | VAF 43/424 reads (10%) | called by muse, mutect2, varscan2
- COL21A1 | c.1868G>T p.G623V | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A5 | c.3832G>A p.G1278R | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.463); called by muse, mutect2
- CORO2B | c.643C>A p.L215M | Missense Mutation (SNP) | VAF 33/266 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- CPS1 | c.2317A>G p.I773V | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2
- CPXM2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.011); called by muse, mutect2
- CROCC2 | c.3401G>T p.R1134L | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- CTBP1 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2
- CWH43 | c.1372G>C p.G458R | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CXXC5 | c.697A>G p.S233G | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CYP19A1 | c.1223C>A p.P408H | Missense Mutation (SNP) | VAF 56/347 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CYP24A1 | c.1151C>A p.S384Y | Missense Mutation (SNP) | VAF 23/383 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CYP26B1 | c.1022del p.G341Afs*69 | Frame Shift Del (DEL) | VAF 28/163 reads (17%) | called by mutect2, pindel, varscan2
- CYRIB | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DACH2 | c.1060C>A p.Q354K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- DCAF4L2 | c.396G>T p.W132C | Missense Mutation (SNP) | VAF 40/395 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCBLD2 | c.484G>C p.G162R | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DCDC1 | c.1245G>C p.Q415H | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); called by muse, mutect2
- DEF8 | c.389A>T p.H130L (on ENST00000268676 / NM_207514.3; = p.H69L on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/253 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- DENND1B | c.1188G>T p.R396S | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DHX9 | c.2792G>T p.G931V | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DMD | c.1904C>T p.S635L | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- DMXL1 | c.5888C>G p.S1963C | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2
- DNAI1 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 39/534 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.15); called by muse, mutect2
- DOCK2 | c.4510A>T p.T1504S | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOT1L | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSC1 | c.1719C>A p.H573Q | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- DSEL | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- DSG3 | c.1082C>G p.S361C | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DSG3 | c.2590G>C p.D864H | Missense Mutation (SNP) | VAF 16/456 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2
- DST | c.15481G>A p.E5161K (on ENST00000361203 / NM_001374722.1; = p.E2749K on NM_015548.5) | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.808); called by muse, mutect2
- DYNC1H1 | c.3964G>T p.A1322S | Missense Mutation (SNP) | VAF 44/542 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.22); called by muse, mutect2
- DYNC2I1 | c.1071G>T p.K357N | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- DYSF | c.2716G>T p.D906Y | Missense Mutation (SNP) | VAF 69/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFCAB8 | c.80C>A p.A27D | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EHBP1L1 | c.2038G>T p.E680* | Nonsense Mutation (SNP) | VAF 24/269 reads (9%) | called by muse, mutect2
- EMID1 | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- EML4 | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- EML4 | c.734A>T p.D245V | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- EPB41L4B | c.620T>A p.L207H | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- ERICH5 | c.95G>T p.S32I | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, varscan2
- ERMP1 | c.272C>G p.S91W | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ERN1 | c.2605G>T p.V869L | Missense Mutation (SNP) | VAF 45/333 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- ESM1 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ESR1 | c.1699C>A p.H567N | Missense Mutation (SNP) | VAF 43/497 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- EXOC6 | c.197G>T p.C66F | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EYS | c.1638C>A p.D546E | Missense Mutation (SNP) | VAF 33/377 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2
- F8 | c.4137G>C p.K1379N | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- FAM120B | c.2021del p.X674_splice | Splice Site (DEL) | VAF 6/71 reads (8%) | called by mutect2, pindel
- FAM131C | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- FAM135A | c.953G>T p.W318L (on ENST00000370479 / NM_001351599.1; = p.W301L on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAM135B | c.1691C>A p.S564Y | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM71B | c.677C>G p.A226G | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2
- FANCM | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.151); called by muse, mutect2
- FAT1 | c.3134A>G p.E1045G | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAT3 | c.12745C>A p.L4249M | Missense Mutation (SNP) | VAF 41/298 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- FCGR2A | c.336C>A p.S112R (on ENST00000271450 / NM_001136219.3; = p.S111R on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCRL1 | c.883A>T p.T295S | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.591); called by muse, varscan2
- FHAD1 | c.2614C>A p.L872I | Missense Mutation (SNP) | VAF 54/333 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FMN2 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FNDC3B | c.2294G>A p.G765E | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- FOXK1 | c.2125G>T p.E709* | Nonsense Mutation (SNP) | VAF 22/238 reads (9%) | called by muse, mutect2
- FRMPD2 | c.2896G>T p.G966C | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FYN | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2
- GABRA1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 34/310 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRA1 | c.735C>G p.H245Q | Missense Mutation (SNP) | VAF 34/335 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- GABRB2 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 51/358 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GABRG3 | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- GAS2L3 | c.982A>T p.K328* | Nonsense Mutation (SNP) | VAF 32/185 reads (17%) | called by muse, mutect2, varscan2
- GCGR | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 17/311 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- GFRAL | c.496C>G p.Q166E | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.012); called by muse, mutect2
- GLB1L3 | c.812-1G>T p.X271_splice | Splice Site (SNP) | VAF 28/322 reads (9%) | called by muse, mutect2
- GLDC | c.2559G>T p.R853S | Missense Mutation (SNP) | VAF 86/550 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by mutect2, varscan2
- GLI1 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 15/143 reads (10%) | called by muse, mutect2, varscan2
- GOLGA5 | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- GOLGB1 | c.6767+1G>T p.X2256_splice | Splice Site (SNP) | VAF 12/75 reads (16%) | called by muse, varscan2
- GPR32 | c.902G>T p.S301I | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- GRB14 | c.1294+1G>T p.X432_splice | Splice Site (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2, varscan2
- GRID2 | c.1862G>T p.G621V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRK1 | c.700-1G>T p.X234_splice | Splice Site (SNP) | VAF 27/189 reads (14%) | called by muse, mutect2, varscan2
- HCN1 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.012); called by muse, mutect2
- HDAC1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HELB | c.2755G>T p.G919C | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC2 | c.2478G>T p.E826D | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HHAT | c.96C>G p.H32Q | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- HOXB5 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HOXC8 | c.687del p.E230Rfs*111 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | called by mutect2, pindel
- HS3ST3A1 | c.405G>T p.E135D | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HSPA6 | c.1834C>A p.L612I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HUWE1 | c.1849G>T p.G617C | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.340del p.Y114Tfs*3 | Frame Shift Del (DEL) | VAF 31/213 reads (15%) | called by mutect2, pindel, varscan2
- IGKV3D-7 | c.303C>A p.S101R | Missense Mutation (SNP) | VAF 33/609 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.011); called by muse, mutect2
- IMPG2 | c.2034G>T p.E678D | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- INTS2 | c.37A>T p.T13S | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQSEC3 | c.2479G>T p.V827L (on ENST00000538872 / NM_001170738.2; = p.V524L on NM_015232.1) | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- IRAG2 | c.4173G>T p.K1391N (on ENST00000636465; = p.K436N on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ITGA1 | c.1754G>T p.G585V | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- ITGAD | c.877G>T p.G293* | Nonsense Mutation (SNP) | VAF 15/154 reads (10%) | called by muse, mutect2
- ITGAL | c.722+1G>T p.X241_splice | Splice Site (SNP) | VAF 46/326 reads (14%) | called by muse, mutect2, varscan2
- ITPR2 | c.2581A>C p.T861P | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITPRID1 | c.1793G>A p.R598K | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); called by muse, mutect2
- JPH4 | c.1803G>T p.P601= | Splice Region (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2
- KALRN | c.4327C>A p.L1443M | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNB1 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KCNB2 | c.411C>A p.C137* | Nonsense Mutation (SNP) | VAF 18/239 reads (8%) | called by muse, mutect2
- KCNK10 | c.1214C>A p.T405N | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCP | c.730G>T p.G244C (on ENST00000620378; = p.G301C on NM_001366122.1) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KERA | c.352A>G p.S118G | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KIAA1671 | c.4313G>T p.G1438V | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- KIF18A | c.104A>T p.H35L | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.21); called by muse, mutect2
- KIF18B | c.1934G>T p.R645L (on ENST00000593135 / NM_001265577.2; = p.R657L on NM_001264573.2) | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF6 | c.1594C>A p.Q532K | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.95); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KIF6 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KLHL3 | c.1321G>T p.G441W | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KNL1 | c.5786C>T p.P1929L (on ENST00000346991 / NM_170589.5; = p.P1903L on NM_144508.5) | Missense Mutation (SNP) | VAF 49/306 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KNL1 | c.6635G>T p.W2212L (on ENST00000346991 / NM_170589.5; = p.W2186L on NM_144508.5) | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- KRT3 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 81/538 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- KRT34 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 79/636 reads (12%) | called by muse, mutect2, varscan2
- KRT6B | c.1603A>T p.T535S | Missense Mutation (SNP) | VAF 30/432 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- LCE2D | c.175A>T p.S59C | Missense Mutation (SNP) | VAF 110/455 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- LDHB | c.-6-2A>T | Splice Site (SNP) | VAF 78/344 reads (23%) | called by muse, mutect2, varscan2
- LDHC | c.655G>T p.G219* | Nonsense Mutation (SNP) | VAF 16/198 reads (8%) | called by muse, mutect2
- LIG1 | c.977A>T p.D326V | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRFN2 | c.1484G>T p.W495L | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- LTBP1 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MACF1 | c.21989C>T p.S7330F (on ENST00000372915; = p.S5375F on NM_012090.5) | Missense Mutation (SNP) | VAF 31/255 reads (12%) | called by muse, mutect2, varscan2
- MAGI2 | c.3782G>T p.G1261V | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAN2B1 | c.2142G>T p.W714C | Missense Mutation (SNP) | VAF 34/494 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAP3K13 | c.1448A>G p.Y483C | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- MED13 | c.6413A>T p.N2138I | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, varscan2
- METTL24 | c.668T>A p.L223H | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); called by muse, mutect2
- MGAM2 | c.6500C>A p.T2167K | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- MROH2A | c.494T>A p.L165Q | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- MROH2B | c.1736A>T p.K579I | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- MRPS2 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTFR2 | c.29A>T p.E10V | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- MTMR4 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 58/295 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MXRA5 | c.1205G>C p.R402T | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MYBPC2 | c.2023G>C p.V675L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, varscan2
- MYH1 | c.2921C>G p.A974G | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MYH7 | c.4006G>T p.A1336S | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MYH8 | c.5468G>T p.R1823L | Missense Mutation (SNP) | VAF 68/466 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MYO3A | c.731+5G>A | Splice Region (SNP) | VAF 26/412 reads (6%) | called by muse, mutect2
- NAT8L | c.516C>G p.I172M | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- NAV3 | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NBAS | c.2202+1G>T p.X734_splice | Splice Site (SNP) | VAF 9/181 reads (5%) | called by muse, mutect2
- NBPF12 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2
- NCAM2 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 15/177 reads (8%) | called by muse, mutect2
- NCKAP1 | c.3224A>T p.K1075I | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- NEK10 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 34/284 reads (12%) | called by muse, mutect2, varscan2
- NGFR | c.567G>T p.E189D | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- NIN | c.6054G>C p.R2018S (on ENST00000382041 / NM_182946.1; = p.R1305S on NM_016350.4) | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NLGN1 | c.833G>C p.G278A | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- NLRP14 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 42/444 reads (9%) | called by muse, mutect2
- NME5 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOC4L | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NPAP1 | c.2779G>T p.G927C | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- NPC1L1 | c.1951C>A p.L651M | Missense Mutation (SNP) | VAF 60/515 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP205 | c.999G>T p.W333C | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPN4 | c.1421A>T p.Q474L | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10D3 | c.772G>T p.V258F | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- OR2M5 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 107/387 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- OR2T12 | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 82/474 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2V2 | c.416A>T p.Q139L | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- OR4C46 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- OR52N4 | c.679G>T p.V227L | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- OR52N5 | c.623G>C p.G208A | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5M11 | c.594G>T p.M198I | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.255); called by muse, mutect2
- OR5T2 | c.430del p.C144Vfs*20 | Frame Shift Del (DEL) | VAF 31/219 reads (14%) | called by mutect2, pindel, varscan2
- ORC5 | c.356C>G p.T119S | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- OVCH2 | c.1220C>A p.A407D | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.586); called by muse, mutect2
- P2RX1 | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- P2RX1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- PADI4 | c.908A>T p.Q303L | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PAPOLA | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); called by muse, mutect2
- PAPSS1 | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PASD1 | c.122T>G p.L41* | Nonsense Mutation (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- PCDHB1 | c.561C>A p.H187Q | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- PCDHB5 | c.823G>T p.G275W | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA2 | c.1628G>T p.S543I | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PCDHGB5 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE10A | c.1161C>A p.S387R | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.811); called by muse, mutect2
- PEAK1 | c.4167G>T p.Q1389H | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PERM1 | c.2099C>A p.P700H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2
- PFDN4 | c.226A>T p.I76F | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2
- PHF20L1 | c.471C>A p.D157E | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.028); called by muse, varscan2
- PIEZO2 | c.2587G>T p.G863W | Missense Mutation (SNP) | VAF 85/481 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- PIEZO2 | c.244G>T p.V82L | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- PIGG | c.2216G>T p.G739V (on ENST00000453061 / NM_001127178.3; = p.G731V on NM_017733.4) | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIK3AP1 | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 8/197 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- PIK3CG | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIP5K1C | c.1971G>T p.Q657H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2
- PIP5K1C | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 39/501 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2
- PKHD1 | c.8368G>T p.D2790Y | Missense Mutation (SNP) | VAF 24/503 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- PKHD1 | c.6763G>T p.D2255Y | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PKHD1L1 | c.499A>T p.R167* | Nonsense Mutation (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- PLA2G6 | c.953A>T p.N318I | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2
- PLAU | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLEC | c.7689G>C p.E2563D (on ENST00000322810 / NM_201380.4; = p.E2453D on NM_000445.5) | Missense Mutation (SNP) | VAF 28/426 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.531); called by muse, mutect2
- PLK5 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLXNA4 | c.3968G>T p.R1323L | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POLL | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- POMT2 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 36/510 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- POTEG | c.1119C>A p.S373R | Missense Mutation (SNP) | VAF 21/560 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2
- POTEJ | c.2756G>T p.R919L | Missense Mutation (SNP) | VAF 116/872 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); called by muse, varscan2
- PPEF2 | c.1724G>T p.S575I | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PPP2R1B | c.1495T>A p.L499I | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- PPP3CB | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PPP4R3C | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PRDM10 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 18/183 reads (10%) | called by muse, mutect2
- PRKDC | c.8639G>T p.C2880F | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- PRKDC | c.2934+1G>T p.X978_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | called by muse, varscan2
- PRKX | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRPF31 | c.697G>C p.G233R | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PRR16 | c.37T>A p.C13S | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRRX2 | c.463C>A p.R155S | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRX | c.1910C>G p.P637R | Missense Mutation (SNP) | VAF 106/661 reads (16%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- PSMB9 | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PTCHD4 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.783G>C p.W261C (on ENST00000421990 / NM_001136042.2; = p.W243C on NM_025267.3) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- PTPRC | c.1621G>T p.V541L | Missense Mutation (SNP) | VAF 110/379 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PTPRS | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.031); called by muse, mutect2
- PTPRT | c.2720C>T p.A907V | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2
- RAB1A | c.182A>T p.K61M | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RAD51AP2 | c.3437A>T p.Y1146F | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RANGAP1 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 12/231 reads (5%) | called by muse, mutect2
- RAPGEF2 | c.4248A>T p.E1416D | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RBBP8NL | c.650A>T p.Q217L | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RBFOX3 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 20/339 reads (6%) | called by muse, mutect2
- RBP3 | c.2597C>A p.T866K | Missense Mutation (SNP) | VAF 103/659 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REPIN1 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); called by muse, mutect2
- REPIN1 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RHOT2 | c.1404+1G>T p.X468_splice | Splice Site (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2, varscan2
- RIOK1 | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- RNF14 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 60/507 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ROR1 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 16/343 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.062); called by muse, mutect2
- RRP7A | c.178A>T p.T60S | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTL9 | c.2876C>G p.S959C | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- RXYLT1 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- RYR1 | c.6647G>T p.G2216V | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RYR2 | c.14533A>G p.I4845V | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, varscan2
- SEMA5B | c.269A>T p.E90V | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SENP2 | c.1400A>T p.E467V | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2
- SERPINE3 | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SGO2 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 16/238 reads (7%) | called by muse, mutect2
- SHH | c.939G>T p.Q313H | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2
- SKIV2L | c.2884A>G p.T962A | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLA2 | c.10C>A p.L4M | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.293); called by muse, mutect2
- SLC11A1 | c.697T>A p.C233S | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2
- SLC12A5 | c.216+3G>A | Splice Region (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- SLC16A10 | c.715A>T p.I239F | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); called by muse, mutect2
- SLC17A6 | c.1597C>T p.Q533* | Nonsense Mutation (SNP) | VAF 12/290 reads (4%) | called by muse, mutect2
- SLC22A12 | c.1661A>T p.*554Lext*65 | Nonstop Mutation (SNP) | VAF 62/438 reads (14%) | called by muse, mutect2, varscan2
- SLC23A3 | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 20/247 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.601); called by muse, mutect2
- SLC24A4 | c.501C>A p.D167E | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SLC38A5 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); called by muse, mutect2
- SLC5A3 | c.1412T>A p.F471Y | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC6A19 | c.1016C>A p.T339K | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.009); called by muse, mutect2
- SLC6A4 | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 51/295 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SLC6A7 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC9A3 | c.1597A>T p.N533Y | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- SLCO5A1 | c.1162G>C p.A388P | Missense Mutation (SNP) | VAF 52/331 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SLIT1 | c.3230G>T p.G1077V | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMG1 | c.6699C>G p.A2233= | Splice Region (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- SNRNP200 | c.2636A>G p.Y879C | Missense Mutation (SNP) | VAF 61/376 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNTG2 | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- SORCS1 | c.2352G>T p.Q784H | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.396); called by muse, mutect2
- SPAG5 | c.3190G>T p.E1064* | Nonsense Mutation (SNP) | VAF 24/245 reads (10%) | called by muse, mutect2
- SPATA16 | c.312C>A p.D104E | Missense Mutation (SNP) | VAF 171/720 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, varscan2
- SPDYC | c.596C>A p.P199Q | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- SPG7 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 89/508 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.481); called by muse, varscan2
- SPON1 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- SPTA1 | c.6316G>T p.D2106Y | Missense Mutation (SNP) | VAF 60/338 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STON2 | c.1743G>T p.R581S (on ENST00000649389 / NM_001366849.2; = p.R524S on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/285 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.941); called by muse, mutect2
- STPG4 | c.451A>T p.K151* | Nonsense Mutation (SNP) | VAF 27/242 reads (11%) | called by muse, mutect2, varscan2
- SVEP1 | c.7682C>A p.P2561H | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); called by muse, mutect2
- SYNE2 | c.9575G>A p.C3192Y | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2
- SYNPR | c.19-7C>A | Splice Region (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2, varscan2
- TAF4 | c.1512_1516del p.V506Gfs*18 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | called by mutect2, pindel
- TAFA1 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- TBC1D8B | c.131-1G>T p.X44_splice | Splice Site (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- TDRD7 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 57/487 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TELO2 | c.856G>C p.G286R | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TENM2 | c.3162G>T p.Q1054H (on ENST00000518659 / NM_001122679.2; = p.Q822H on NM_001080428.3) | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TEP1 | c.3067G>A p.A1023T | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TFB1M | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 29/297 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.259); called by muse, mutect2
- THRB | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 23/424 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.713); called by muse, mutect2
- TIMM23 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2
- TIMM23B | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 16/339 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.152); called by muse, mutect2
- TM4SF5 | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- TM7SF2 | c.250-4G>A | Splice Region (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- TMEM131 | c.3974C>T p.P1325L | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.034); called by muse, mutect2
- TMEM200A | c.950G>C p.S317T | Missense Mutation (SNP) | VAF 18/279 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- TMEM63C | c.746T>A p.V249D | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.062); called by muse, mutect2
- TMTC1 | c.658G>T p.E220* (on ENST00000539277 / NM_001193451.2; = p.E112* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 37/311 reads (12%) | called by muse, mutect2, varscan2
- TNC | c.5800G>A p.G1934S | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.206); called by muse, mutect2
- TNFRSF21 | c.998G>T p.R333M | Missense Mutation (SNP) | VAF 33/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- TNFRSF4 | c.371-2A>T p.X124_splice | Splice Site (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- TNFSF11 | c.91C>G p.H31D | Missense Mutation (SNP) | VAF 25/348 reads (7%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.362); called by muse, mutect2
- TNS1 | c.3755G>T p.G1252V | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2
- TPGS2 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TRAK1 | c.2483G>T p.R828L | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.402); called by muse, mutect2
- TRAV13-2 | c.55A>G p.S19G | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2
- TRIM64 | c.711C>A p.H237Q | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.732); called by muse, mutect2
- TRIM64 | c.713T>C p.V238A | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- TSBP1 | c.1264C>A p.Q422K (on ENST00000617061; = p.Q427K on NM_006781.5) | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.546); called by muse, mutect2
- TSPAN16 | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- TTC3 | c.3125C>A p.S1042* | Nonsense Mutation (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- TTLL5 | c.3041G>T p.G1014V | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.062); called by muse, mutect2
- TUBA3C | c.183C>A p.H61Q | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); called by muse, mutect2
- TWNK | c.1089G>T p.W363C | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.423); called by muse, mutect2
- UBC | c.1609G>C p.V537L | Missense Mutation (SNP) | VAF 62/472 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, varscan2
- UHRF1BP1L | c.4033G>T p.D1345Y | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- UPF1 | c.3340G>T p.G1114* (on ENST00000599848 / NM_001297549.2; = p.G1103* on NM_002911.4) | Nonsense Mutation (SNP) | VAF 23/129 reads (18%) | called by muse, mutect2, varscan2
- USH2A | c.2935G>T p.G979W | Missense Mutation (SNP) | VAF 78/352 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTP6 | c.450G>T p.W150C | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.289); called by muse, mutect2
- VCAN | c.7504C>A p.P2502T | Missense Mutation (SNP) | VAF 35/346 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- VN1R2 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- VSIG10L | c.2243G>T p.R748L | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- WDFY4 | c.5690C>A p.P1897H | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2
- WDR12 | c.1122-4T>C | Splice Region (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- WDR62 | c.2262G>T p.Q754H | Missense Mutation (SNP) | VAF 98/559 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- WDR90 | c.5230G>T p.E1744* | Nonsense Mutation (SNP) | VAF 20/272 reads (7%) | called by muse, mutect2
- WWC2 | c.2669G>C p.G890A | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XPOT | c.2888G>C p.*963Sext*10 | Nonstop Mutation (SNP) | VAF 9/224 reads (4%) | called by muse, mutect2
- YARS2 | c.892T>G p.S298A | Missense Mutation (SNP) | VAF 24/508 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2
- ZFHX2 | c.769C>G p.Q257E | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFYVE26 | c.3456G>T p.L1152F | Missense Mutation (SNP) | VAF 78/572 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by muse, mutect2
- ZNF251 | c.1930C>A p.R644S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- ZNF469 | c.6088C>A p.P2030T (on ENST00000437464; = p.P2058T on NM_001367624.2) | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZNF518A | c.309G>C p.E103D | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.14); called by muse, mutect2
- ZNF521 | c.2327T>C p.L776P | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF8 | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZNFX1 | c.1813G>T p.A605S | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZSCAN2 | c.1492G>T p.G498* | Nonsense Mutation (SNP) | VAF 32/165 reads (19%) | called by muse, mutect2, varscan2
- ABCC5 | c.1714C>T p.L572= | Silent (SNP) | VAF 34/464 reads (7%) | catalogued as rs1192296314; called by muse, mutect2
- ACKR1 | c.462C>A p.G154= | Silent (SNP) | VAF 31/156 reads (20%) | called by muse, mutect2, varscan2
- ADAM32 | c.2136C>A p.A712= | Silent (SNP) | VAF 29/136 reads (21%) | called by muse, mutect2, varscan2
- ADCY2 | c.1230G>T p.V410= | Silent (SNP) | VAF 25/253 reads (10%) | called by muse, mutect2
- ADGRA2 | c.478C>A p.R160= | Silent (SNP) | VAF 33/220 reads (15%) | catalogued as COSV100177810; called by muse, mutect2, varscan2
- AKAP13 | c.5109G>T p.R1703= (on ENST00000394518 / NM_007200.5; = p.R1707= on NM_006738.6) | Silent (SNP) | VAF 49/339 reads (14%) | called by muse, mutect2, varscan2
- AKR1B1 | c.168G>T p.G56= | Silent (SNP) | VAF 103/593 reads (17%) | called by muse, mutect2, varscan2
- ALPK3 | c.4881C>T p.G1627= | Silent (SNP) | VAF 12/312 reads (4%) | called by muse, mutect2
- AMPH | c.1326T>A p.A442= | Silent (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- ANKRD11 | c.3765A>G p.K1255= | Silent (SNP) | VAF 38/546 reads (7%) | called by muse, mutect2
- ANKRD33B | c.1365C>T p.I455= | Silent (SNP) | VAF 49/302 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.2538C>T p.I846= | Silent (SNP) | VAF 49/295 reads (17%) | called by muse, mutect2, varscan2
- ARHGAP9 | c.2160A>T p.P720= (on ENST00000393797 / NM_001319850.2; = p.P701= on NM_032496.4) | Silent (SNP) | VAF 30/386 reads (8%) | called by muse, mutect2
- ATP2B2 | c.420G>T p.G140= | Silent (SNP) | VAF 34/285 reads (12%) | catalogued as COSV59495208; called by muse, mutect2, varscan2
- ATP8A2 | c.1674A>G p.E558= | Silent (SNP) | VAF 16/293 reads (5%) | called by muse, mutect2
- BBS9 | c.957A>G p.T319= | Silent (SNP) | VAF 30/400 reads (8%) | called by muse, mutect2
- BICRA | c.1680G>T p.S560= | Silent (SNP) | VAF 14/112 reads (13%) | called by muse, mutect2, varscan2
- C17orf64 | c.159A>G p.K53= | Silent (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2, varscan2
- CACNA1B | c.1065C>G p.L355= | Silent (SNP) | VAF 17/187 reads (9%) | catalogued as rs200389919; called by muse, mutect2
- CACNA1C | c.3687C>T p.I1229= | Silent (SNP) | VAF 16/198 reads (8%) | called by muse, mutect2
- CACNA1E | c.2583G>T p.G861= | Silent (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- CACNB2 | c.1170C>A p.A390= (on ENST00000324631 / NM_201596.3; = p.A335= on NM_000724.4) | Silent (SNP) | VAF 35/407 reads (9%) | catalogued as rs767828060; called by muse, mutect2
- CACTIN | c.393G>T p.A131= | Silent (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- CADM2 | c.774T>A p.P258= (on ENST00000407528 / NM_001167674.2; = p.P260= on NM_153184.4) | Silent (SNP) | VAF 10/84 reads (12%) | called by muse, varscan2
- CALB1 | c.21G>A p.Q7= | Silent (SNP) | VAF 25/230 reads (11%) | called by muse, mutect2, varscan2
- CAMK2B | c.396C>A p.V132= | Silent (SNP) | VAF 20/216 reads (9%) | catalogued as COSV51658316; called by muse, mutect2
- CD200R1 | c.231C>A p.I77= (on ENST00000471858 / NM_170780.3; = p.I100= on NM_138806.4) | Silent (SNP) | VAF 60/332 reads (18%) | catalogued as rs769593708, COSV55601148; called by muse, mutect2, varscan2
- CDH10 | c.1329A>T p.T443= | Silent (SNP) | VAF 12/336 reads (4%) | called by muse, mutect2
- CDH23 | c.6873C>A p.P2291= | Silent (SNP) | VAF 21/306 reads (7%) | called by muse, mutect2
- CDHR2 | c.1644G>T p.R548= | Silent (SNP) | VAF 48/494 reads (10%) | called by muse, mutect2
- CEACAM20 | c.522G>T p.G174= | Silent (SNP) | VAF 20/203 reads (10%) | called by muse, mutect2, varscan2
- CEP164 | c.3957C>A p.A1319= | Silent (SNP) | VAF 35/292 reads (12%) | called by muse, mutect2, varscan2
- CLDN10 | c.327C>A p.S109= | Silent (SNP) | VAF 17/185 reads (9%) | called by muse, mutect2
- CNTNAP2 | c.2421C>G p.S807= | Silent (SNP) | VAF 40/358 reads (11%) | called by muse, mutect2, varscan2
- COL3A1 | c.3180G>A p.K1060= | Silent (SNP) | VAF 49/421 reads (12%) | called by muse, mutect2, varscan2
- CRLF3 | c.33G>T p.L11= | Silent (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- CSPG4 | c.4287G>T p.L1429= | Silent (SNP) | VAF 21/114 reads (18%) | called by muse, varscan2
- DBH | c.1713C>A p.V571= | Silent (SNP) | VAF 42/475 reads (9%) | called by muse, mutect2
- DLG5 | c.4293G>C p.V1431= | Silent (SNP) | VAF 31/169 reads (18%) | called by muse, mutect2, varscan2
- DMD | c.6630G>A p.K2210= | Silent (SNP) | VAF 7/143 reads (5%) | catalogued as rs1189398660, COSV58896731; called by muse, mutect2
- DPYSL5 | c.294C>A p.I98= | Silent (SNP) | VAF 24/156 reads (15%) | catalogued as COSV99982843; called by muse, mutect2, varscan2
- DSCAML1 | c.4995G>T p.G1665= (on ENST00000321322; = p.G1605= on NM_020693.4) | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as rs1411175858; called by muse, mutect2, varscan2
- EHBP1L1 | c.2958G>A p.K986= | Silent (SNP) | VAF 22/159 reads (14%) | called by muse, mutect2, varscan2
- EHD4 | c.1350C>T p.V450= | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as rs1204169079, COSV55003079; called by muse, mutect2
- FAM170B | c.333G>T p.T111= | Silent (SNP) | VAF 34/205 reads (17%) | catalogued as COSV61253754; called by muse, mutect2, varscan2
- FBXO33 | c.480G>T p.A160= | Silent (SNP) | VAF 90/580 reads (16%) | catalogued as rs746035437; called by muse, mutect2, varscan2
- FGG | c.22C>A p.R8= | Silent (SNP) | VAF 28/225 reads (12%) | catalogued as COSV60195064; called by muse, mutect2, varscan2
- FGG | c.21C>A p.P7= | Silent (SNP) | VAF 29/227 reads (13%) | called by muse, mutect2, varscan2
- FLRT2 | c.900C>A p.S300= | Silent (SNP) | VAF 17/207 reads (8%) | called by muse, mutect2
- FNDC1 | c.4977C>A p.P1659= | Silent (SNP) | VAF 35/428 reads (8%) | called by muse, mutect2
- FZD7 | c.1071G>T p.L357= | Silent (SNP) | VAF 23/276 reads (8%) | called by muse, mutect2
- GIMAP8 | c.1644G>A p.L548= | Silent (SNP) | VAF 24/161 reads (15%) | catalogued as COSV100217544; called by muse, mutect2, varscan2
- GLP2R | c.1401G>T p.L467= | Silent (SNP) | VAF 28/188 reads (15%) | called by muse, varscan2
- GNLY | c.279C>G p.T93= | Silent (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- GPR22 | c.708G>A p.Q236= | Silent (SNP) | VAF 32/174 reads (18%) | called by muse, mutect2, varscan2
- GPX3 | c.648G>A p.R216= | Silent (SNP) | VAF 25/260 reads (10%) | called by muse, mutect2, varscan2
- H1-7 | c.660C>G p.A220= | Silent (SNP) | VAF 26/476 reads (5%) | catalogued as rs897871572; called by muse, mutect2
- HECW2 | c.210G>A p.L70= | Silent (SNP) | VAF 44/265 reads (17%) | catalogued as rs777995926; called by muse, mutect2, varscan2
- HGD | c.1035C>T p.L345= | Silent (SNP) | VAF 32/697 reads (5%) | catalogued as rs1342717829; called by muse, mutect2
- HGF | c.1299T>C p.S433= | Silent (SNP) | VAF 28/376 reads (7%) | called by muse, mutect2
- HIVEP2 | c.1302G>T p.P434= | Silent (SNP) | VAF 28/266 reads (11%) | called by muse, mutect2, varscan2
- HLA-G | c.354C>A p.T118= | Silent (SNP) | VAF 31/197 reads (16%) | catalogued as COSV64405113; called by muse, mutect2, varscan2
- HOXA11 | c.672G>T p.S224= | Silent (SNP) | VAF 48/365 reads (13%) | called by muse, varscan2
- HSPA12B | c.1890C>G p.L630= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- IFNA4 | c.348G>A p.L116= | Silent (SNP) | VAF 12/331 reads (4%) | called by muse, mutect2
- IGF2BP1 | c.357G>T p.T119= | Silent (SNP) | VAF 31/179 reads (17%) | catalogued as COSV51732473; called by muse, mutect2, varscan2
- IGHV1-45 | c.231C>T p.T77= | Silent (SNP) | VAF 18/374 reads (5%) | called by muse, mutect2
- INTS1 | c.3024G>A p.E1008= | Silent (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2
- ITGB3 | c.480G>C p.L160= | Silent (SNP) | VAF 86/449 reads (19%) | catalogued as COSV71383361; called by muse, mutect2, varscan2
- KCNK2 | c.981A>T p.A327= (on ENST00000444842 / NM_001017425.3; = p.A312= on NM_014217.4) | Silent (SNP) | VAF 22/140 reads (16%) | called by muse, varscan2
- KCNS3 | c.931C>A p.R311= | Silent (SNP) | VAF 24/259 reads (9%) | catalogued as rs369862362; called by muse, mutect2
- KEL | c.894C>A p.L298= | Silent (SNP) | VAF 30/352 reads (9%) | called by muse, mutect2
- KIAA1549 | c.5757G>A p.Q1919= (on ENST00000422774 / NM_001164665.2; = p.Q1903= on NM_020910.3) | Silent (SNP) | VAF 42/280 reads (15%) | called by muse, mutect2, varscan2
- KIAA1586 | c.1413T>A p.T471= | Silent (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- KIF16B | c.2328C>T p.I776= | Silent (SNP) | VAF 11/214 reads (5%) | called by muse, mutect2
- KIFAP3 | c.1824G>T p.V608= | Silent (SNP) | VAF 32/218 reads (15%) | called by muse, mutect2, varscan2
- LRFN5 | c.576C>A p.S192= | Silent (SNP) | VAF 13/177 reads (7%) | catalogued as COSV53264722; called by muse, mutect2
- LRP4 | c.2142G>T p.L714= | Silent (SNP) | VAF 30/552 reads (5%) | catalogued as rs1347257826, COSV66134858; called by muse, mutect2
- LRWD1 | c.633C>T p.N211= | Silent (SNP) | VAF 20/276 reads (7%) | called by muse, mutect2
- LTBP1 | c.1347A>T p.P449= (on ENST00000404816 / NM_206943.4; = p.P123= on NM_000627.4) | Silent (SNP) | VAF 45/328 reads (14%) | called by muse, mutect2, varscan2
- LVRN | c.546G>T p.A182= | Silent (SNP) | VAF 31/343 reads (9%) | catalogued as rs535266514; called by muse, mutect2
- LYG2 | c.492C>A p.P164= | Silent (SNP) | VAF 37/326 reads (11%) | catalogued as COSV100283618; called by muse, mutect2, varscan2
- MAP3K4 | c.1317G>A p.E439= | Silent (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- MARK1 | c.678G>A p.E226= | Silent (SNP) | VAF 58/476 reads (12%) | called by muse, mutect2, varscan2
- MEF2D | c.819C>T p.I273= | Silent (SNP) | VAF 55/469 reads (12%) | catalogued as COSV100560009, COSV61727442; called by muse, mutect2, varscan2
- MROH2B | c.1083C>A p.I361= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as COSV68181305; called by muse, mutect2, varscan2
- MS4A8 | c.366C>A p.S122= | Silent (SNP) | VAF 24/202 reads (12%) | called by muse, mutect2, varscan2
- MTTP | c.1704C>A p.P568= | Silent (SNP) | VAF 49/372 reads (13%) | called by muse, mutect2, varscan2
- MUC3A | c.936C>T p.T312= | Silent (SNP) | VAF 32/312 reads (10%) | catalogued as rs77135444; called by muse, mutect2, varscan2
- MZF1 | c.1635G>A p.E545= | Silent (SNP) | VAF 42/233 reads (18%) | catalogued as rs780511000; called by muse, mutect2, varscan2
- NAV3 | c.3936C>T p.F1312= | Silent (SNP) | VAF 20/428 reads (5%) | called by muse, mutect2
- NAV3 | c.6699T>A p.S2233= (on ENST00000397909 / NM_001024383.2; = p.S2211= on NM_014903.6) | Silent (SNP) | VAF 14/101 reads (14%) | called by muse, varscan2
- NLRC5 | c.1947C>T p.T649= | Silent (SNP) | VAF 34/560 reads (6%) | catalogued as rs752649595; called by muse, mutect2
- NPAS3 | c.2172G>C p.A724= (on ENST00000356141 / NM_001164749.2; = p.A692= on NM_022123.3) | Silent (SNP) | VAF 20/189 reads (11%) | called by muse, mutect2, varscan2
- NPC1L1 | c.2380C>T p.L794= | Silent (SNP) | VAF 30/380 reads (8%) | catalogued as COSV99212716; called by muse, mutect2
- OR10G7 | c.417G>T p.S139= | Silent (SNP) | VAF 53/317 reads (17%) | called by muse, mutect2, varscan2
- OR10G8 | c.591C>A p.V197= | Silent (SNP) | VAF 45/276 reads (16%) | catalogued as rs1469704639; called by muse, mutect2, varscan2
- OR10T2 | c.132G>C p.V44= | Silent (SNP) | VAF 84/462 reads (18%) | called by muse, mutect2, varscan2
- OR2L2 | c.672C>T p.V224= | Silent (SNP) | VAF 12/370 reads (3%) | catalogued as rs1439595950; called by muse, mutect2
- OR4C6 | c.606G>C p.G202= | Silent (SNP) | VAF 24/352 reads (7%) | catalogued as COSV58605298; called by muse, mutect2
- OR4M1 | c.834T>A p.T278= | Silent (SNP) | VAF 22/316 reads (7%) | called by muse, mutect2
- OR51F2 | c.48G>T p.L16= | Silent (SNP) | VAF 22/175 reads (13%) | called by muse, mutect2, varscan2
- OR52J3 | c.300G>T p.V100= | Silent (SNP) | VAF 18/306 reads (6%) | catalogued as COSV100984965; called by muse, mutect2
- OR52L1 | c.504G>C p.V168= | Silent (SNP) | VAF 15/227 reads (7%) | called by muse, mutect2
- OR8D1 | c.549C>G p.P183= | Silent (SNP) | VAF 27/230 reads (12%) | catalogued as COSV100766574, COSV63443105; called by muse, mutect2, varscan2
- OTOP1 | c.1095G>T p.G365= | Silent (SNP) | VAF 36/440 reads (8%) | catalogued as rs1183024830; called by muse, mutect2
- PAGR1 | c.423C>T p.A141= | Silent (SNP) | VAF 39/271 reads (14%) | called by muse, mutect2, varscan2
- PCDH11X | c.3465G>T p.P1155= | Silent (SNP) | VAF 53/381 reads (14%) | catalogued as COSV100011742; called by muse, mutect2, varscan2
- PCDHA1 | c.1356G>T p.A452= | Silent (SNP) | VAF 86/614 reads (14%) | catalogued as rs1324578987, COSV65377384; called by muse, mutect2, varscan2
- PCDHB11 | c.2178G>T p.S726= | Silent (SNP) | VAF 39/332 reads (12%) | catalogued as rs202157565, COSV100696935; called by muse, mutect2, varscan2
- PCDHGA1 | c.1956C>A p.P652= | Silent (SNP) | VAF 51/477 reads (11%) | catalogued as rs751791278; called by muse, mutect2, varscan2
- PCNX1 | c.4242A>T p.T1414= | Silent (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- PIP4P2 | c.441A>T p.P147= | Silent (SNP) | VAF 34/304 reads (11%) | called by muse, mutect2
- PLCB4 | c.751C>A p.R251= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- PLCL2 | c.609C>T p.F203= (on ENST00000615277 / NM_001144382.2; = p.F77= on NM_015184.5) | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV67620646; called by muse, mutect2
- PLXNA1 | c.2808G>T p.L936= | Silent (SNP) | VAF 48/288 reads (17%) | called by muse, mutect2, varscan2
- POM121L2 | c.2334C>A p.A778= | Silent (SNP) | VAF 61/442 reads (14%) | called by muse, mutect2, varscan2
- PRAMEF12 | c.1206G>C p.G402= | Silent (SNP) | VAF 74/520 reads (14%) | called by muse, mutect2, varscan2
- PRDM13 | c.1194G>A p.E398= | Silent (SNP) | VAF 16/234 reads (7%) | catalogued as rs1176928682; called by muse, mutect2
- PRDM6 | c.1299G>T p.L433= | Silent (SNP) | VAF 43/329 reads (13%) | called by muse, mutect2, varscan2
- PRKAG2 | c.1599G>T p.V533= | Silent (SNP) | VAF 36/369 reads (10%) | called by muse, mutect2
- PRPH2 | c.996G>A p.V332= | Silent (SNP) | VAF 57/357 reads (16%) | called by muse, mutect2, varscan2
- PTGER1 | c.183G>C p.A61= | Silent (SNP) | VAF 16/246 reads (7%) | catalogued as rs1232456014; called by muse, mutect2
- RAB29 | c.147C>G p.L49= | Silent (SNP) | VAF 69/637 reads (11%) | called by muse, mutect2, varscan2
- RALYL | c.120C>G p.A40= | Silent (SNP) | VAF 28/402 reads (7%) | catalogued as COSV72818224; called by muse, mutect2
- RAPH1 | c.396C>G p.T132= | Silent (SNP) | VAF 19/237 reads (8%) | called by muse, mutect2
- RASAL2 | c.87G>T p.L29= | Silent (SNP) | VAF 58/397 reads (15%) | called by muse, mutect2, varscan2
- RBMXL2 | c.696C>A p.A232= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV100182090; called by muse, mutect2, varscan2
- RGS9 | c.378C>A p.A126= | Silent (SNP) | VAF 36/482 reads (7%) | catalogued as COSV52225733; called by muse, mutect2
- RPS19 | c.201G>T p.R67= | Silent (SNP) | VAF 40/231 reads (17%) | called by muse, mutect2, varscan2
- RYR1 | c.10135C>T p.L3379= | Silent (SNP) | VAF 45/344 reads (13%) | catalogued as COSV104416301; called by muse, mutect2, varscan2
- SALL1 | c.2223G>T p.R741= | Silent (SNP) | VAF 78/488 reads (16%) | catalogued as rs1430868205; called by muse, mutect2, varscan2
- SDK1 | c.5952G>T p.A1984= | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as COSV67360860; called by muse, mutect2
- SELENON | c.1248G>T p.R416= | Silent (SNP) | VAF 45/242 reads (19%) | catalogued as COSV100823479; called by muse, mutect2, varscan2
- SIGLEC1 | c.2166C>A p.G722= | Silent (SNP) | VAF 29/285 reads (10%) | called by muse, mutect2, varscan2
- SLAMF1 | c.54T>A p.A18= | Silent (SNP) | VAF 29/384 reads (8%) | called by muse, mutect2
- SLC12A3 | c.618C>A p.L206= | Silent (SNP) | VAF 84/466 reads (18%) | called by muse, mutect2, varscan2
- SLC36A3 | c.1215C>A p.A405= | Silent (SNP) | VAF 33/279 reads (12%) | called by muse, mutect2, varscan2
- SLC9C2 | c.549C>T p.L183= | Silent (SNP) | VAF 19/147 reads (13%) | called by muse, mutect2, varscan2
- SOHLH1 | c.555G>T p.A185= | Silent (SNP) | VAF 34/302 reads (11%) | catalogued as COSV53680720; called by muse, mutect2
- SPPL2C | c.1128C>T p.S376= | Silent (SNP) | VAF 21/399 reads (5%) | called by muse, mutect2
- SSTR1 | c.489C>T p.I163= | Silent (SNP) | VAF 15/350 reads (4%) | called by muse, mutect2
- STRA6 | c.1441C>T p.L481= | Silent (SNP) | VAF 89/634 reads (14%) | called by muse, mutect2, varscan2
- SULF2 | c.1299G>A p.E433= | Silent (SNP) | VAF 20/242 reads (8%) | called by muse, mutect2
- TANC2 | c.1320G>T p.R440= | Silent (SNP) | VAF 50/249 reads (20%) | called by muse, mutect2, varscan2
- TBC1D9B | c.2094G>T p.V698= | Silent (SNP) | VAF 34/478 reads (7%) | called by muse, mutect2
- TBCK | c.765C>T p.T255= (on ENST00000273980 / NM_001163436.4; = p.T192= on NM_033115.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/146 reads (14%) | catalogued as COSV56762008; called by muse, mutect2, varscan2
- TBX2 | c.1420T>C p.L474= | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- TJP2 | c.1632G>T p.A544= | Silent (SNP) | VAF 26/302 reads (9%) | called by muse, mutect2
- TMEM132A | c.2055C>A p.S685= (on ENST00000453848 / NM_178031.3; = p.S686= on NM_017870.4) | Silent (SNP) | VAF 28/275 reads (10%) | called by muse, mutect2
- TMEM132E | c.2160G>T p.R720= (on ENST00000321639; = p.R810= on NM_001304438.2) | Silent (SNP) | VAF 30/300 reads (10%) | catalogued as COSV100396571; called by muse, mutect2
- TMEM156 | c.174G>T p.V58= | Silent (SNP) | VAF 44/295 reads (15%) | catalogued as COSV60744011; called by mutect2, varscan2
- TMEM184C | c.202T>C p.L68= | Silent (SNP) | VAF 26/264 reads (10%) | called by muse, mutect2, varscan2
- TMEM185A | c.726C>A p.S242= | Silent (SNP) | VAF 16/308 reads (5%) | called by muse, mutect2
- TNRC6B | c.1992G>T p.G664= | Silent (SNP) | VAF 20/217 reads (9%) | called by muse, mutect2
- TRADD | c.855G>T p.L285= | Silent (SNP) | VAF 43/173 reads (25%) | called by muse, mutect2, varscan2
- TREM2 | c.84G>T p.A28= | Silent (SNP) | VAF 28/239 reads (12%) | catalogued as COSV100632692, COSV58295852; called by muse, mutect2, varscan2
- TRIM13 | c.801A>G p.L267= | Silent (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- TTN | c.8598T>A p.A2866= (on ENST00000591111; = p.A2820= on NM_003319.4) | Silent (SNP) | VAF 65/418 reads (16%) | called by muse, mutect2, varscan2
- UNC80 | c.5733C>A p.R1911= | Silent (SNP) | VAF 9/136 reads (7%) | called by muse, mutect2
- USH2A | c.11403C>A p.P3801= | Silent (SNP) | VAF 80/358 reads (22%) | called by muse, varscan2
- WWC1 | c.1893T>C p.S631= | Silent (SNP) | VAF 21/198 reads (11%) | catalogued as COSV99514467; called by muse, mutect2, varscan2
- WWC3 | c.3051G>T p.R1017= | Silent (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- ZDHHC14 | c.456C>A p.T152= | Silent (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- ZFYVE26 | c.3454T>C p.L1152= | Silent (SNP) | VAF 78/582 reads (13%) | catalogued as rs755944154; called by muse, mutect2
- ZNF469 | c.996C>A p.P332= | Silent (SNP) | VAF 76/348 reads (22%) | called by muse, mutect2, varscan2
- ZNF500 | c.948G>T p.R316= | Silent (SNP) | VAF 28/286 reads (10%) | called by muse, mutect2
- ZNF585A | c.828A>G p.G276= (on ENST00000292841 / NM_001288800.2; = p.G221= on NM_152655.3) | Silent (SNP) | VAF 37/252 reads (15%) | catalogued as rs748937252; called by muse, mutect2, varscan2
- ZNF676 | c.753T>C p.H251= (on ENST00000650058; = p.H219= on NM_001001411.3) | Silent (SNP) | VAF 20/366 reads (5%) | called by muse, mutect2
- ZNF787 | c.339G>A p.R113= | Silent (SNP) | VAF 20/118 reads (17%) | called by muse, mutect2, varscan2
- ZNF99 | c.2547T>C p.N849= | Silent (SNP) | VAF 72/337 reads (21%) | called by muse, mutect2, varscan2
- ZNF99 | c.1401C>T p.A467= | Silent (SNP) | VAF 74/343 reads (22%) | catalogued as rs1424357416; called by muse, mutect2, varscan2
- ZSCAN5A | c.673C>T p.L225= | Silent (SNP) | VAF 49/257 reads (19%) | called by muse, mutect2, varscan2
- AC012485.1 | n.365G>A | RNA (SNP) | VAF 34/552 reads (6%) | called by muse, mutect2
- AC022272.1 | n.123+1364T>C | Intron (SNP) | VAF 21/156 reads (13%) | called by muse, mutect2, varscan2
- AC026410.1 | n.464C>T | RNA (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- AC136628.2 | n.551G>A | RNA (SNP) | VAF 18/309 reads (6%) | catalogued as rs1209924622; called by muse, mutect2
- ADAD2 | c.419-328T>A | Intron (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- ADAM8 | c.-7C>G | 5'UTR (SNP) | VAF 15/148 reads (10%) | called by muse, mutect2, varscan2
101 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 101 other) are not listed here.
